Somatic mutation profile of tumor specimen 0DWKH9 from CCDI case PBCMMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,420 days).
Specimen 0DWKH9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb3878eb-dd20-48cd-bd9a-d5a52d0539ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWKFX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1354c64b-3c2e-4090-b4a1-dae5ce5117e6

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRC6A | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 166/616 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, varscan2
- SRGAP3 | c.*73C>A | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
